FM case AD2576 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/dc67be45-cd5b-45a9-a101-757b407537c3

Male, 53.7 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; primary biopsied or resected from the ureter. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
